Surgical pathology report (de-identified scan), TCGA case TCGA-XF-A9SZ, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Southern California, specimen TCGA-XF-A9SZ-01A (Primary Tumor).

[page 1 of 6]
Collected
Orders

DIAGNOSIS:

RADICAL CYSTECTOMY WITH BILATERAL LYMPH NODE DISSECTION, ILEAL CONDUIT DIVERSION AND G-TUBE PLACEMENT:

RIGHT DISTAL URETER (A):

INTRAOPERATIVE FROZEN SECTION DIAGNOSIS:

- NEGATIVE

FINAL DIAGNOSIS:

- BENIGN URETER

- NO UROTHELIAL DYSPLASIA OR CARCINOMA IDENTIFIED

LEFT DISTAL URETER (B):

INTRAOPERATIVE FROZEN SECTION DIAGNOSIS:

- NEGATIVE

FINAL DIAGNOSIS:

- BENIGN URETER

- NO UROTHELIAL DYSPLASIA OR CARCINOMA IDENTIFIED

BLADDER / PROSTATE (C):

INTRAOPERATIVE GROSS DIAGNOSIS:

- TUMOR IDENTIFIED

FINAL DIAGNOSIS:

BLADDER:

- POORLY DIFFERENTIATED UROTHELIAL CARCINOMA, GRADE 4/4, INFILTRATING THROUGH THE MUSCULARIS PROPRIA TO THE PERIVESICAL FAT BUT DOES NOT INVOLVE THE RESECTION MARGIN
- LYMPHOVASCULAR INVASION IDENTIFIED
- RIGHT URETER AND BLADDER JUNCTION INVOLVED BY UROTHELIAL CARCINOMA BUT WITH NEGATIVE MARGIN
- FOCAL UROTHELIAL CARCINOMA IN SITU (FLAT LESION)
- ALL SURGICAL MARGINS, FREE OF MALIGNANCY
- CHRONIC CYSTITIS

PERIVESICAL LYMPH NODES:

- NO METASTATIC CARCINOMA IDENTIFIED IN SEVEN LYMPH NODES EXAMINED (0/7)

PROSTATE:

- MULTIFOCAL HIGH GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA (PIN II-III)
- NO INVASIVE CARCINOMA IDENTIFIED
- ACUTE AND CHRONIC PROSTATITIS
- PROSTATIC ATROPHY
- CHRONIC PERIARITRITIS

RIGHT PARACAVAL LYMPH NODES (D):

- METASTATIC CARCINOMA IDENTIFIED IN ONE OUT OF SEVEN LYMPH NODES EXAMINED (1/7)

RIGHT COMMON ILIAC LYMPH NODES (E):

- METASTATIC CARCINOMA IDENTIFIED IN FOUR OUT OF 13 LYMPH NODES EXAMINED (4/13), THE LARGEST ONE IS UP TO 1.8 CM WITHOUT EXTRANODAL INVOLVEMENT

INFERIOR MESENTERIC ARTERY NODE (F):

- NO METASTATIC CARCINOMA IDENTIFIED IN THREE LYMPH NODES EXAMINED (0/3)

PRESACRAL LYMPH NODES (G):

- NO METASTATIC CARCINOMA IDENTIFIED IN TWO LYMPH NODES EXAMINED (0/2)

RIGHT EXTERNAL ILIAC LYMPH NODES (H):

ICD-O-3

Carcinoma, urothelial NOS

8/20/13

Site Bladder NOS

C67.9

7/23/26/14

[page 2 of 6]
- NO METASTATIC CARCINOMA IDENTIFIED IN THREE LYMPH NODES EXAMINED (0/3)

RIGHT NODE OF CLOQUET (I):

- NO METASTATIC CARCINOMA IDENTIFIED IN TWO LYMPH NODES EXAMINED (0/2)

RIGHT OBTURATOR / HYPOGASTRIC LYMPH NODES (J):

- NO METASTATIC CARCINOMA IDENTIFIED IN 21 LYMPH NODES EXAMINED (0/21)

LEFT PARA AORTIC LYMPH NODES (K):

- NO METASTATIC CARCINOMA IDENTIFIED IN SEVEN LYMPH NODES EXAMINED (0/7)

LEFT COMMON ILIAC LYMPH NODES (L):

- METASTATIC CARCINOMA IDENTIFIED IN ONE OUT OF EIGHT LYMPH NODES EXAMINED (1/8)

LEFT NODE OF CLOQUET (M):

- NO METASTATIC CARCINOMA IDENTIFIED IN ONE LYMPH NODE EXAMINED (0/1)

LEFT EXTERNAL ILIAC LYMPH NODES (N):

- NO METASTATIC CARCINOMA IDENTIFIED IN TWO LYMPH NODES EXAMINED (0/2)

LEFT OBTURATOR / HYPOGASTRIC LYMPH NODES (O):

- NO METASTATIC CARCINOMA IDENTIFIED IN 14 LYMPH NODES EXAMINED (0/14)

RIGHT PRESACRIC LYMPH NODES (P):

- NO METASTATIC CARCINOMA IDENTIFIED IN FIVE LYMPH NODES EXAMINED (0/5)

LEFT PRESACRIC LYMPH NODES (Q):

- NO METASTATIC CARCINOMA IDENTIFIED IN 12 LYMPH NODES EXAMINED (0/12)

RIGHT PROXIMAL URETER [MARGIN] (R):

- BENIGN URETER
- NO UROTHELIAL DYSPLASIA OR CARCINOMA IDENTIFIED

LEFT PROXIMAL URETER [MARGIN] (S):

- BENIGN URETER
- NO UROTHELIAL DYSPLASIA OR CARCINOMA IDENTIFIED

LYMPH NODE SUMMARY: METASTATIC CARCINOMA IDENTIFIED IN TOTAL OF SIX
OUT OF 107 LYMPH NODES EXAMINED (6/107)

PATHOLOGIC TNM STAGE: T3bN2MX (AJCC-5TH EDITION)

SPECIMEN SOURCE:

A: "R. distal ureter F/S"
B: "Left distal ureter F/S"
C: "Bladder/prostate"

[page 3 of 6]
Collected:
Ordered by:

Location:

D: "R. para caval lymph nodes"
E: "R. common iliac L. nodes"
F: "IMA node"
G: "Presacral L. nodes"
H: "R. external iliac L. nodes"
I: "R. node of cloquet"
J: "R. obturator/hypogastric L. nodes"
K: "L. para aortic L. nodes"
L: "L. common iliac L. nodes"
M: "L. node of cloquet"
N: "L. external iliac L. node"
O: "L. obturator/hypogastric L. nodes"
P: "r. presciatic L. node"
Q: "L. presciatic L. nodes"
R: "R. proximal ureter (margin)"
S: "L. proximal ureter (margin)"

CLINICAL INFORMATION:

Pre-Op Dx: Bladder cancer

Post-Op Dx: Same

GROSS EXAMINATION:

A: The specimen is received fresh from the O.R. and labeled "R. distal ureter F/S". It consists of a portion of ureter measuring 0.2 cm in length by 0.3 cm in diameter. The specimen is entirely submitted for frozen section in cassette AFS.

B: The specimen is received fresh from the O.R. and labeled "Left distal ureter F/S". It consists of a portion of ureter with attached fat measuring 0.3 cm in length by 0.4 cm in diameter. The specimen is entirely submitted for frozen section in cassette BFS.

C: The specimen is received fresh from the O.R. and labeled "Bladder/prostate". It consists of a cystoprostatectomy specimen measuring 19 x 14.5 x 5 cm. Attached is a peritoneal segment measuring 18.5 x 14.5 x 0.1 cm. The peritoneum is smooth and glistening. The prostate measures 5 x 4.5 x 3 cm with attached right seminal vesicle which measures 2.5 x 1.2 x 0.5 cm and the left seminal vesicle measures 2.1 x 1.2 x 0.5 cm. Also contiguous is a right distal ureter which measures 6 cm in length and 0.6 cm in circumference, and the left ureter measures 6.5 cm in length and 0.5 cm in circumference. The bladder measures 8 x 7 x 4 cm. Opening the bladder along the anterior wall reveals a 7.5 x 4.5 x 3.5 cm gray-white tumor mass which occupies the anterior wall and the right lateral wall, that comes within 1 cm from the right ureterovesical junction. The tumor grossly involves the bladder wall and comes to within 0.2 cm from the inked serosal margin. The uninvolved bladder wall measures 0.4 cm in thickness. The urethra measures 3 cm in length and 0.9 cm in circumference with normal-appearing mucosa. The outer surface of the prostate is inked black with superimposed red on the right side. Sectioning of the prostate reveals multiple pink-tan soft nodules up to 0.4 cm in greatest diameter. Sectioning of the perivesical fat reveals a 2 x 1 cm firm area on the perivesical fat. At the request of the surgeon, an intraoperative gross consultation was performed in order to aid in the care of this patient. Representative sections are submitted in 39 cassettes.

D: The specimen is received in formalin and labeled "R. para caval lymph nodes". It consists of a 6 x 4 x 1 cm fatty tissue fragment. Sectioning reveals one lymph node which measures 1.5 cm in greatest diameter. Totally embedded in three cassettes.

E: The specimen is received in formalin and labeled "R. common iliac L. nodes". It consists of a 3 x 3 x 2 cm matted lymph nodes with surrounding fat. Totally

[page 4 of 6]
Collected:
Ordered by:

embedded in five cassettes.

F: The specimen is received in formalin and labeled "IMA node". It consists of a 4 x 3 x 2 cm gray-tan soft tissue fragment. Bisected and totally embedded in one cassette.

G: The specimen is received formalin and labeled "Presacral L. nodes". It consists of a 6 x 4 x 0.5 cm fibromembranous fragment with fat. Totally embedded in four cassettes.

H: The specimen is received in formalin and labeled "R. external iliac L. nodes". It consists of a 3 x 2 x 2 cm fibromembranous tissue fragment and fat. Totally embedded in four cassettes.

I: The specimen is received in formalin and labeled "R. node of cloquet". It consists of a 0.3 x 0.3 x 0.2 cm lymph node. The lymph node is bisected and totally embedded in one cassette..

J: The specimen is received in formalin and labeled "R. obturator/hypogastric L. nodes". It consists of a 6 x 5 x 2 cm fibromembranous tissue fragment and fat. Totally embedded in six cassettes.

K: The specimen is received in formalin and labeled "L. para aortic L. nodes". It consists of a 2 x 1 x 0.5 cm fatty tissue fragment. Totally embedded in one cassette.

L: The specimen is received in formalin and labeled "L. common iliac L. nodes". It consists of three lymph nodes ranging from 0.4 up to 0.5 cm in greatest diameter. The lymph nodes are totally submitted in three cassettes.

M: The specimen is received in formalin and labeled "L. node of cloquet". It consists of a 1 x 1 x 0.5 cm fat. The specimen is totally submitted in one cassette.

N: The specimen is received in formalin and labeled "L. external iliac L. node". It consists of a 2 x 1 x 1 cm fatty tissue fragment. Totally embedded in one cassette.

O: The specimen is received in formalin and labeled "L. obturator/hypogastric L. nodes". It consists of a 4 x 3 x 0.5 cm fatty tissue fragment. Sectioning reveals multiple lymph nodes. Totally embedded in four cassettes.

P: The specimen is received in formalin and labeled "r. presciatic L. node". It consists of a 1 x 0.5 x 0.3 cm aggregate of fat. Totally embedded in two cassettes.

Q: The specimen is received in formalin and labeled "L. presciatic L. nodes". It consists of a 1 x 1 x 0.5 cm aggregate of fat. Totally embedded in two cassettes.

R: The specimen is received in formalin and labeled "R. proximal ureter (margin)". It consists of a 1 cm in length and 0.2 cm in diameter portion of ureter with stapled end. The stapled end is inked black. The specimen is trisected and totally submitted in one cassette.

S: The specimen is received in formalin and labeled "L. proximal ureter (margin)". It consists of a 1.2 cm in length and 0.2 cm in diameter portion of ureter. The specimen is serially sectioned and totally submitted in one cassette.

SECTIONS:

AFS: frozen section, right distal ureter
BFS: frozen section, left distal ureter

[page 5 of 6]
Collected
Ordered

Location

C1,2: tumor with closest inked serosal margin
C3,4: contiguous section of tumor
C5-10: representative sections of tumor
C11: random section of posterior bladder wall
C12: random section of trigone
C13: section from left lateral wall
C14: bladder dome
C15: right ureterovesical junction
C16: left ureterovesical junction
C17: right apex
C18: left apex
C19: right upper distal prostate
C20: right lower distal prostate
C21: left upper distal prostate
C22: left lower distal prostate
C23: right upper mid prostate
C24: right lower mid prostate
C25: left upper mid prostate
C26: left lower mid prostate
C27: right upper proximal prostate
C28: right lower proximal prostate
C29: left upper proximal prostate
C30: left lower proximal prostate
C31: left upper base prostate
C32: right lower base prostate
C33: left upper base prostate
C34: left lower base prostate
C35: right seminal vesical and vas deferens
C36: left seminal vesical and vas deferens
C37-39: firm area in right perivesical fat
D1: right paracaval lymph nodes; one lymph node
D2,3: remaining tissue
E1-5: right common iliac lymph nodes
F: inferior mesenteric artery node - all embedded
G1-4: left presacral nodes - all embedded
H1-4: right external iliac lymph nodes - all embedded
I: right node of Cloquet - all embedded
J1-6: right obturator/hypogastric lymph nodes - all embedded
K: left para-aortic lymph nodes - all embedded
L1-3: left common iliac lymph nodes - all embedded
M: left node of Cloquet - all embedded
N: left external iliac lymph node - all embedded
O1-4: left obturator/hypogastric lymph nodes - all embedded
P1,2: right presciatic lymph node - all embedded
Q1,2: left presciatic lymph nodes - all embedded
R: right proximal ureter (margin) - all embedded
S: left proximal ureter (margin) - all embedded

INTRAOPERATIVE FROZEN CONSULTATION:

AFS: Right distal ureter:
- benign

BFS: Left distal ureter:
- benign

[page 6 of 6]
Collecta Ordered	Location
---------------------	----------

INTRAOPERATIVE GROSS CONSULTATION

Bladder (C):
- tumor identified

MICROSCOPIC EXAMINATION:

A-S: See final microscopic-diagnosis.1

Source: NCI Genomic Data Commons file 4dc0bb5b-2511-40bd-849f-99869fcebe26 (TCGA-XF-A9SZ.BBDDB909-1AE0-4F10-948A-DAA989CF87D2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).